Gene-level copy-number profile of tumor specimen ALCH-AERJ-TTP1-A from ALCHEMIST case ALCH-AERJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.5 years (21,735 days).
Specimen ALCH-AERJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bbb3a2bf-62d5-4ffe-b8a1-fc45c09af1dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AERJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,760 have no estimate.
https://portal.gdc.cancer.gov/files/38f5e70d-77d3-436e-ab16-fa61a8ae6cf3

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 103; copy number 2: 529; copy number 3: 1,001; copy number 4: 20,028; copy number 5: 9,063; copy number 6: 19,678; copy number 7: 4,081; copy number 8: 3,552; copy number 9: 674; copy number 10: 86; copy number 11: 35; copy number 13: 4; copy number 14: 8; copy number 16: 1; copy number 17: 3; copy number 21: 12; copy number 26: 3.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:177,379,235–177,400,661, 2 genes: SLC34A1, PFN3.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:6,615,389–6,866,635, 6 genes, copy number 17–26 (within-gene range 6–26): MIR7515HG, AC097517.1, MIR7515, LINC00487, NRIR, CMPK2.
- chr9:61,190,003–61,582,675, 8 genes, copy number 14: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr14:18,333,726–18,419,273, 4 genes, copy number 13: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
